Gene-level copy-number profile of tumor specimen TCGA-04-1342-01A from TCGA case TCGA-04-1342, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G2; Age at diagnosis: 80.8 years (29,501 days).
Specimen TCGA-04-1342-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.d5aabe0b-7274-49da-9d1a-558f1ef71877.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1342-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9356f22b-44eb-4967-9f86-685c4acda5e4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 7,122; copy number 2: 29,802; copy number 3: 17,700; copy number 4: 4,639; copy number 5: 409; copy number 7: 23; copy number 8: 78; copy number 9: 13; copy number 10: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1342-01A-01D-0428-01): tumor purity 0.79, ploidy 2.35, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 552 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,580,524, 78 genes, copy number 8 (broad region; genes not listed).
- chr1:160,151,586–161,766,227, 92 genes, copy number 5 (broad region; genes not listed).
- chr1:242,882,066–248,919,946, 191 genes, copy number 5 (broad region; genes not listed).
- chr2:66,820,684–67,041,966, 5 genes, copy number 5: DNMT3AP1, AC009474.1, LINC01799, LINC01628, AC007403.1.
- chr2:190,504,338–191,425,389, 19 genes, copy number 5 (within-gene range 3–5): NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B.
- chr12:24,212,421–30,321,617, 118 genes, copy number 5–10 (broad region; genes not listed).
- chr19:28,869,507–31,466,431, 49 genes, copy number 5–9: AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791, AC025809.1, AC025809.2, AC008992.1, AC008794.1.

Autosomal genes at a single copy (total copy number 1): 4,701. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
